Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4SV, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4SV-01A (Primary Tumor).

. Surgical Pathology
Requested RV:

TISSUE DESCRIPTION:
Left lower lobe lung and portion of lingula (475 grams, 17 x 9.7 x 6.3 cm), aortic lymph nodes (aortopulmonary and anterior mediastinal), inferior mediastinal (subcarinal and inferior pulmonary ligament) and N1 (interlobar) lymph nodes A1, A2, A3, A4, A5, B1, B2, B3, B4, B5, B6, B7

DIAGNOSIS:
Lung, left lower lobe and lingula, lobectomy: Grade 3 (of 4) adenocarcinoma forming a 3.2 x 3 x 2.5 cm peripheral mass extending to but not invading the visceral pleura. The bronchial margin and multiple (7) intrapulmonary peribronchial lymph nodes are negative for malignancy.

Lymph nodes, aortic, inferior mediastinal and N1, excision: Multiple aortic (4 aortopulmonary and 1 anterior mediastinal), inferior mediastinal (2 subcarinal and 2 inferior pulmonary ligament) and N1 (4 interlobar) lymph nodes are negative for tumor.

100-0-3
adenocarcinoma, NOS 8140/3
Site: lung, ^④ lower lobe 034.3
lw
10/27/12

Source: NCI Genomic Data Commons file f107d408-b3bd-49e0-8453-1509c035c5ea (TCGA-MP-A4SV.8E809652-9783-4B7A-B92D-8C393A2940AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).